Somatic mutation profile of tumor specimen TCGA-17-Z057-01A (aliquot TCGA-17-Z057-01A-01W-0747-08) from TCGA case TCGA-17-Z057, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z057-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68b66c75-720c-42be-acf8-7bffa12da8a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z057-11A (Solid Tissue Normal), aliquot TCGA-17-Z057-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14000be0-5734-48d9-94e9-b68c31356a46

The open-access MAF lists 429 somatic variants for this specimen: 328 protein-altering or splice-affecting, 97 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 283, Silent 97, Nonsense Mutation 19, Frame Shift Del 9, Splice Site 6, Splice Region 4, Frame Shift Ins 3, Translation Start Site 2, Intron 2, In Frame Del 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXL2 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as CM082718, COSV57725966, COSV57728681; called by muse, mutect2
- KMT2D | c.5149C>T p.Q1717* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as rs1157281284, COSV99981892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 152/270 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ABCB1 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV55944671, COSV55953251; called by muse, mutect2, varscan2
- ADIPOQ | c.221T>C p.I74T | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs138835949; called by muse, varscan2
- AHNAK | c.12391A>G p.M4131V | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as rs368256739; called by muse, mutect2, varscan2
- ANKS1B | c.849G>T p.E283D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV61349421; called by muse, mutect2, varscan2
- ASB2 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs372274381, COSV100279170; called by muse, mutect2, varscan2
- ATP13A4 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 36/636 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs780171151; called by muse, mutect2
- AZU1 | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52140960; called by muse, mutect2, varscan2
- BRCA2 | c.4945A>G p.K1649E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs763743962, COSV66453234; called by muse, mutect2, varscan2
- CATSPERG | c.1551C>G p.I517M | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53046865, COSV99044165; called by muse, mutect2
- CCDC73 | c.2199G>A p.M733I | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs753249671; called by muse, mutect2, varscan2
- CCL13 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as rs762960516; called by muse, mutect2, varscan2
- CD163L1 | c.3104G>A p.R1035Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768411637; called by muse, mutect2, varscan2
- CDH11 | c.501C>A p.N167K | Missense Mutation (SNP) | VAF 76/479 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV51764659; called by muse, mutect2, varscan2
- CDKN2A | c.213C>G p.N71K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as CD044135, CM980328, COSV58687044, COSV58695272, COSV58699200, COSV58713592, COSV58721900; called by muse, mutect2, varscan2
- CFAP126 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs534604465; called by muse, mutect2, varscan2
- CFH | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs138890387, CM134084, COSV66408057; called by muse, mutect2, varscan2
- COBLL1 | c.2602C>T p.P868S (on ENST00000392717; = p.P830S on NM_014900.5) | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1333820110; called by muse, mutect2, varscan2
- CUEDC1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748549021, COSV64226143; called by muse, mutect2, varscan2
- CUL3 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52366847; called by muse, mutect2, varscan2
- DARS2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.241); catalogued as COSV99508939; called by muse, mutect2, varscan2
- DUOX1 | c.248C>G p.S83* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99973431; called by muse, mutect2, varscan2
- EIF4G3 | c.2614A>G p.T872A | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.089); catalogued as rs1292767310; called by muse, mutect2, varscan2
- ELAC2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV62033934; called by muse, mutect2
- ERICH3 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs189806920, COSV58605989; called by muse, mutect2, varscan2
- FAT1 | c.8138C>G p.S2713* | Nonsense Mutation (SNP) | VAF 59/171 reads (35%) | catalogued as COSV71675818, COSV71676303; called by muse, mutect2
- FBN1 | c.5051G>A p.G1684E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1414890312; called by muse, mutect2, varscan2
- FBXL17 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 26/168 reads (15%) | catalogued as COSV62849595; called by muse, mutect2, varscan2
- FLT1 | c.3041C>T p.S1014F | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs747942952; called by muse, mutect2, varscan2
- GFPT2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779219580; called by muse, mutect2, varscan2
- GGN | c.473C>G p.P158R | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as rs758549937, COSV99287485; called by muse, mutect2, varscan2
- HOXD8 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs774294577, COSV100497055, COSV100497193; called by muse, mutect2
- HS6ST3 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.084); catalogued as rs1331474154, COSV65014061; called by muse, mutect2, varscan2
- HSPG2 | c.4363G>C p.E1455Q | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV65973738; called by muse, mutect2, varscan2
- IFI6 | c.147A>C p.G49= | Splice Region (SNP) | VAF 13/58 reads (22%) | catalogued as rs1347754787; called by muse, mutect2
- IGKV1D-13 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs745366200; called by mutect2, varscan2
- KATNBL1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV56624336; called by muse, mutect2, varscan2
- KDR | c.3700G>A p.V1234M | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.736); catalogued as rs1457048123, COSV55760197, COSV99816424; called by muse, mutect2
- KDR | c.3552G>C p.L1184F | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.942); catalogued as COSV55770954; called by muse, mutect2, varscan2
- KIF20B | c.3625C>T p.Q1209* (on ENST00000371728 / NM_001284259.2; = p.Q1169* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | catalogued as rs1471768031, COSV53304165; called by muse, mutect2, varscan2
- LAIR1 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as COSV57307126; called by muse, mutect2
- LBHD1 | c.301C>T p.L101F (on ENST00000431002 / NM_001367940.1; = p.L75F on NM_024099.3) | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV63473240; called by muse, mutect2, varscan2
- LIG4 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV63598397; called by muse, mutect2, varscan2
- LRIG3 | c.2084-1G>C p.X695_splice | Splice Site (SNP) | VAF 20/85 reads (24%) | catalogued as COSV57866487; called by muse, mutect2
- LRRTM1 | c.1048G>T p.G350C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99703196; called by muse, mutect2, varscan2
- MAPK6 | c.766C>A p.R256S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as COSV55929225; called by muse, mutect2, varscan2
- MARK3 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551785219; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MBD5 | c.1173G>C p.M391I | Missense Mutation (SNP) | VAF 64/529 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV68698964; called by muse, mutect2, varscan2
- MECOM | c.1234G>C p.D412H (on ENST00000468789 / NM_001105078.4; = p.D600H on NM_004991.4) | Missense Mutation (SNP) | VAF 25/436 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52963288; called by muse, mutect2
- MRGPRX2 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV61674982; called by muse, mutect2, varscan2
- MTUS1 | c.2135C>G p.S712C | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as rs554726229; called by muse, mutect2, varscan2
- MYH8 | c.3508C>T p.R1170W | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67975050; called by muse, mutect2, varscan2
- MYOF | c.5813C>G p.A1938G | Missense Mutation (SNP) | VAF 73/468 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs764412531; called by muse, mutect2, varscan2
- NLRP13 | c.1463T>C p.I488T | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1568694461; called by muse, mutect2
- NME7 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs748946443; called by mutect2, varscan2
- NOS1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs374847966; called by muse, mutect2, varscan2
- NPAT | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 32/189 reads (17%) | catalogued as rs553229900, COSV99585709; called by muse, varscan2
- NUDT9 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs1467361197; called by muse, mutect2, varscan2
- OLFML2B | c.950-1G>A p.X317_splice | Splice Site (SNP) | VAF 13/101 reads (13%) | catalogued as rs749424526; called by muse, mutect2, varscan2
- OOEP | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.712); catalogued as COSV100949896, COSV64859053; called by muse, mutect2, varscan2
- OPRK1 | c.432del p.S145Afs*5 | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | catalogued as COSV55570477; called by mutect2, pindel, varscan2
- OR10Z1 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV63524679; called by muse, mutect2, varscan2
- OR2T4 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 125/307 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs151201153, COSV63543315; called by muse, mutect2, varscan2
- OR5D14 | c.739C>A p.L247M | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV59455852; called by muse, mutect2
- OR5F1 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53545171; called by muse, mutect2
- OR5I1 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.716); catalogued as rs1239931522, COSV56887200; called by muse, mutect2, varscan2
- OSBPL11 | c.38C>G p.S13W | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs944709220, COSV56174941, COSV56176511; called by muse, mutect2, varscan2
- PAX6 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM030267; called by muse, mutect2, varscan2
- PCDH18 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100787070, COSV61272406; called by mutect2, varscan2
- PCDHA9 | c.2236G>C p.G746R | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); catalogued as COSV100969275; called by muse, mutect2, varscan2
- PCDHB10 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99504710; called by muse, mutect2, varscan2
- PCDHB15 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as rs1224877053, COSV51431200; called by muse, mutect2, varscan2
- PCDHGA3 | c.878A>T p.H293L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as rs1490049668; called by muse, mutect2
- PCYT1B | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 42/97 reads (43%) | catalogued as COSV63264482; called by muse, mutect2, varscan2
- PDE5A | c.1240T>A p.Y414N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV99308779; called by muse, mutect2, varscan2
- PFKFB4 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 25/131 reads (19%) | PolyPhen possibly damaging (0.848); catalogued as rs761570064, COSV99219404; called by muse, mutect2, varscan2
- PLXNA2 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as rs1378994323; called by muse, mutect2, varscan2
- POU3F3 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63721146; called by muse, mutect2, varscan2
- POU3F3 | c.1291C>G p.P431A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63722453; called by muse, mutect2, varscan2
- PRMT7 | c.989G>C p.G330A | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs747894195; called by muse, varscan2
- PROM2 | c.2441G>T p.S814I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as COSV58297272; called by muse, mutect2, varscan2
- PRPSAP1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as rs780467217, COSV100221766, COSV61211814; called by muse, mutect2, varscan2
- RAP2C | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61683332; called by muse, mutect2, varscan2
- RIPK3 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV53475101; called by muse, mutect2, varscan2
- RNF10 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201217014; called by muse, mutect2, varscan2
- ROBO4 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.543); catalogued as rs372037630, COSV60628590; called by muse, mutect2, varscan2
- RPRD2 | c.3641C>T p.S1214F | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.352); catalogued as rs767836041; called by muse, mutect2, varscan2
- RPS6KC1 | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65302279; called by muse, mutect2, varscan2
- SBK2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs34316437; called by muse, mutect2
- SCN3A | c.3496G>A p.E1166K | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as COSV51821591; called by muse, mutect2, varscan2
- SCN9A | c.3633T>G p.F1211L (on ENST00000303354; = p.F1200L on NM_002977.3) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as CD072484; called by muse, mutect2
- SDC1 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99587361; called by muse, mutect2, varscan2
- SEC63 | c.1444G>C p.V482L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754389288; called by muse, mutect2, varscan2
- SI | c.951del p.G318Vfs*10 | Frame Shift Del (DEL) | VAF 113/231 reads (49%) | catalogued as COSV100016202; called by mutect2, pindel, varscan2
- SIRPG | c.794A>C p.N265T | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs970135212; called by mutect2, varscan2
- SLC22A10 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60421542; called by muse, mutect2, varscan2
- SLC22A15 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs777793150; called by muse, mutect2
- SLITRK3 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 26/558 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs755352126, COSV53853476; called by muse, mutect2
- SMAD2 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 121/508 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.979); catalogued as COSV50997046; called by mutect2, varscan2
- SPANXN2 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 220/1573 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65127821; called by muse, varscan2
- SRBD1 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs750678667; called by muse, mutect2, varscan2
- STX2 | c.739A>G p.K247E | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.88); catalogued as rs1280417904; called by muse, mutect2, varscan2
- SVIL | c.2024C>T p.S675L (on ENST00000355867 / NM_021738.3; = p.S281L on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV63444437; called by muse, mutect2, varscan2
- SYNE1 | c.25085C>T p.T8362M (on ENST00000367255 / NM_182961.4; = p.T8314M on NM_033071.3) | Missense Mutation (SNP) | VAF 177/619 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs147814237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF2 | c.1651G>T p.D551Y | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65418627; called by muse, mutect2, varscan2
- TBX10 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs745305858; called by muse, mutect2
- TFPI2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs753875527, COSV55990226; called by muse, mutect2, varscan2
- THEMIS | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779371436; called by muse, mutect2, varscan2
- THUMPD2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 107/410 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.058); catalogued as rs1434056845; called by muse, mutect2, varscan2
- TIE1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs747480920, COSV65249033; called by muse, mutect2, varscan2
- TMEM106C | c.555G>A p.V185= | Splice Region (SNP) | VAF 58/222 reads (26%) | catalogued as rs1488312956, COSV56742965, COSV99873505; called by muse, mutect2, varscan2
- TMEM267 | c.21G>C p.K7N | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV67992991; called by muse, mutect2, varscan2
- TNC | c.6083G>A p.R2028K | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60791976; called by muse, mutect2, varscan2
- TNR | c.1687G>T p.A563S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.796); catalogued as COSV54907522, COSV54917514; called by muse, mutect2, varscan2
- TRDN | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV62126421; called by muse, mutect2
- TUT4 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs138715096; called by muse, mutect2, varscan2
- UNC13C | c.3461A>T p.K1154M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as rs1321908326; called by muse, mutect2
- UNC13C | c.4604C>G p.P1535R | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52893830; called by mutect2, varscan2
- VWA3B | c.3812G>C p.R1271P | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs773146578, COSV101417906; called by muse, mutect2, varscan2
- WASHC5 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV100573049, COSV59195979; called by muse, mutect2, varscan2
- ZC3H11A | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276559498, COSV59747320; called by muse, mutect2, varscan2
- ZC3H13 | c.674C>G p.P225R | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99669112; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1242757133; called by muse, mutect2, varscan2
- ZNF343 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs771928502, COSV53855754; called by muse, mutect2, varscan2
- ZNF382 | c.1066G>T p.D356Y | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.842); catalogued as COSV53086561; called by muse, mutect2, varscan2
- ZNF431 | c.1541G>C p.C514S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60673580; called by muse, mutect2, varscan2
- ZNF569 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57594418; called by muse, mutect2, varscan2
- ZNF774 | c.659C>G p.S220* | Nonsense Mutation (SNP) | VAF 68/160 reads (43%) | catalogued as COSV62980837; called by muse, mutect2, varscan2
- ADAMTS20 | c.3659C>G p.S1220* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- AGAP3 | c.1153G>C p.E385Q (on ENST00000622464; = p.E421Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD26 | c.3688G>A p.D1230N | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARFGAP2 | c.463_466del p.F155Qfs*53 | Frame Shift Del (DEL) | VAF 85/455 reads (19%) | called by mutect2, pindel, varscan2
- ARFGAP3 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ARHGAP15 | c.78G>C p.M26I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ARID2 | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BBS7 | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BEND3 | c.1640A>C p.E547A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2
- BEST4 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- BPTF | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- BRF2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- C10orf120 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- C10orf82 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C11orf87 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C2CD2L | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CALU | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CCDC102B | c.1364A>G p.E455G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CCDC141 | c.1939T>A p.Y647N | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- CCSER1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CDHR1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.936); called by muse, mutect2
- CECR2 | c.481G>T p.G161* | Nonsense Mutation (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- CEP162 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CFAP20DC | c.2354A>T p.E785V (on ENST00000482387 / NM_001351530.2; = p.E534V on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CFAP221 | c.2155C>A p.H719N | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHAF1A | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CLDN16 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 145/675 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CMYA5 | c.6746C>T p.P2249L | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN5 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- COL15A1 | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 256/543 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- COL5A2 | c.3535G>C p.G1179R | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRISPLD1 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CRYBA4 | c.560A>T p.Q187L | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CYP7A1 | c.1375A>T p.I459F | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DCTN1 | c.3357G>C p.M1119I | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, varscan2
- DDX31 | c.1610G>T p.S537I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DIDO1 | c.4132G>A p.E1378K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.323); called by muse, mutect2
- DIP2B | c.3823A>C p.N1275H | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, varscan2
- DNAH9 | c.7275G>C p.E2425D | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNTTIP2 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- EEA1 | c.1958del p.S653* | Frame Shift Del (DEL) | VAF 46/172 reads (27%) | called by mutect2, pindel, varscan2
- ENOX2 | c.782-1G>A p.X261_splice (on ENST00000338144 / NM_001382520.1; = p.X232_splice on NM_006375.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 69/111 reads (62%) | called by muse, mutect2, varscan2
- ERBIN | c.1976C>G p.S659C | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FANCA | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FLG | c.4824G>C p.E1608D | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FMO2 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FNDC3B | c.2246G>C p.G749A | Missense Mutation (SNP) | VAF 46/418 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- FPR2 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 50/660 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2
- GCNT4 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GEMIN8 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- GEN1 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- GFRA1 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLIS3 | c.2162G>A p.R721K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GRIPAP1 | c.193_196del p.A65Rfs*7 | Frame Shift Del (DEL) | VAF 100/175 reads (57%) | called by mutect2, pindel, varscan2
- GUCD1 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- HDAC2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- HECW2 | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HELQ | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- HIVEP1 | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HS6ST3 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IGHV1-45 | c.154T>A p.Y52N | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IQGAP2 | c.150G>T p.W50C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ISLR | c.1161C>G p.I387M | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); called by muse, mutect2
- ITSN2 | c.2986G>C p.E996Q | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); called by muse, mutect2
- KCNJ8 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIAA1586 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KIF18A | c.1528A>T p.N510Y | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIF21B | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- KIF6 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KLHL41 | c.1240C>G p.L414V | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- KRTAP10-3 | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- LAMA1 | c.2654G>T p.C885F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LAMA1 | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- LGALS14 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 97/1823 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2
- LNX2 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LRP1B | c.8275A>G p.I2759V | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK2 | c.4960G>A p.E1654K | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- LSG1 | c.542T>A p.V181E | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTA | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAB21L1 | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MAGEE2 | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MAVS | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ME2 | c.1584dup p.K529* | Frame Shift Ins (INS) | VAF 48/249 reads (19%) | called by mutect2, pindel, varscan2
- MESD | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- MGAM | c.3323C>T p.S1108F | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGP | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MKX | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MLLT6 | c.190-1G>A p.X64_splice | Splice Site (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPV17 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MRTFA | c.464A>G p.Q155R | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MSL1 | c.1231C>T p.P411S (on ENST00000398532 / NM_001365919.1; = p.P148S on NM_001012241.2) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.13879G>C p.V4627L | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NAV2 | c.811T>G p.F271V | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- NCKAP5 | c.4373C>A p.A1458E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDN | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- NDST2 | c.1387C>T p.L463F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- NELFCD | c.799G>A p.V267M (on ENST00000602795; = p.V249M on NM_198976.4) | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NES | c.3516G>T p.R1172S | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFIX | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NLRC3 | c.2181G>A p.L727= | Splice Region (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- NLRP9 | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- NLRP9 | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- NOD2 | c.1622G>T p.R541L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NOM1 | c.1131G>T p.M377I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NPR1 | c.1339T>C p.Y447H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- NXT1 | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- OBSCN | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- OBSL1 | c.4585A>G p.T1529A | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2C3 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- OR4D10 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR4S2 | c.801G>C p.K267N | Missense Mutation (SNP) | VAF 147/632 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- OR6X1 | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- OR8D4 | c.60A>T p.Q20H | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR8J1 | c.930C>A p.C310* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | called by muse, mutect2, varscan2
- ORC6 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PCDH15 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH9 | c.1685T>G p.V562G | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PCDH9 | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- PCDH9 | c.629_652del p.L210_T217del | In Frame Del (DEL) | VAF 44/275 reads (16%) | called by mutect2, pindel
- PCDHGA3 | c.879T>A p.H293Q | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2
- PCDHGA9 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.158); called by muse, mutect2
- PCDHGB4 | c.2147C>G p.S716C | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PDE1C | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PDYN | c.709G>C p.V237L | Missense Mutation (SNP) | VAF 112/415 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PKHD1L1 | c.2543T>A p.L848H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PKNOX2 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 37/141 reads (26%) | called by muse, mutect2, varscan2
- PLPP3 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 24/413 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.104); called by muse, mutect2
- PMFBP1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 91/442 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PPIG | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PREX2 | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- PRRC2C | c.4450G>T p.D1484Y (on ENST00000367742; = p.D1482Y on NM_015172.4) | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRD | c.4706T>A p.M1569K | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRG | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PUM3 | c.1865dup p.K623Efs*22 | Frame Shift Ins (INS) | VAF 42/158 reads (27%) | called by mutect2, pindel*, varscan2*
- RB1 | c.2355dup p.P786Sfs*9 | Frame Shift Ins (INS) | VAF 114/465 reads (25%) | called by mutect2, pindel, varscan2
- RBBP6 | c.2350_2351del p.R784* | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- REN | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIC1 | c.3899C>A p.T1300K | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- RMDN3 | c.716_718del p.L239del | In Frame Del (DEL) | VAF 20/94 reads (21%) | called by pindel, varscan2
- RPL10L | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- RPRD2 | c.3062C>G p.S1021* | Nonsense Mutation (SNP) | VAF 85/500 reads (17%) | called by muse, varscan2
- SARAF | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SDC1 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- SEC24A | c.1571C>A p.S524* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- SGSM3 | c.1854-1G>A p.X618_splice | Splice Site (SNP) | VAF 30/148 reads (20%) | called by muse, mutect2, varscan2
- SI | c.3855A>G p.I1285M | Missense Mutation (SNP) | VAF 90/808 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- SLC12A1 | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC12A1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SLC35F6 | c.576C>G p.I192M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, mutect2
- SLC4A10 | c.3013G>A p.A1005T (on ENST00000446997 / NM_001354461.2; = p.A975T on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLCO1B1 | c.2057A>C p.D686A | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLITRK3 | c.2030A>T p.Y677F | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC1B | c.3330C>G p.N1110K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- SPRTN | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- STIL | c.2426C>A p.P809H | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STYXL2 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNE1 | c.11563C>T p.Q3855* (on ENST00000367255 / NM_182961.4; = p.Q3840* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 9/123 reads (7%) | called by muse, mutect2
- TAAR5 | c.748del p.A250Lfs*21 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, varscan2
- TAAR5 | c.747del p.A250Lfs*21 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2*, pindel, varscan2*
- TAPT1 | c.1674G>T p.R558S | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TEP1 | c.4184T>A p.L1395Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TESPA1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TEX13A | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- THRB | c.532T>A p.L178M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TJAP1 | c.757G>T p.G253W (on ENST00000372445 / NM_001146016.1; = p.G243W on NM_080604.3) | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMCO3 | c.1034G>T p.R345I | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TMEM94 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TNC | c.2630G>T p.R877I | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNFRSF10D | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- TOM1L1 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TTLL4 | c.1869_1897+2del p.X623_splice | Splice Site (DEL) | VAF 14/28 reads (50%) | called by mutect2, pindel
- TULP4 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TWNK | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- UBD | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- UBE2G2 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- UBN2 | c.3476G>C p.G1159A | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- UNC93A | c.505del p.L169Ffs*15 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | called by mutect2, pindel, varscan2
- UQCRC2 | c.102A>T p.Q34H | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- USH2A | c.3585T>A p.C1195* | Nonsense Mutation (SNP) | VAF 68/305 reads (22%) | called by muse, mutect2, varscan2
- USP9X | c.5887G>C p.D1963H | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- VWA5A | c.1244+5G>C | Splice Region (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- WDR49 | c.1259G>C p.G420A (on ENST00000308378 / NM_001366158.1; = p.G761A on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/513 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- WNK1 | c.2161C>T p.Q721* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- WWC1 | c.654G>C p.L218F | Missense Mutation (SNP) | VAF 61/441 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFHX4 | c.7397C>G p.S2466C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2
- ZFHX4 | c.8369A>T p.E2790V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ZNF154 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 90/623 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF207 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF217 | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZNF239 | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.552); called by muse, mutect2
- ZNF254 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ZNF382 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 36/498 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- ZNF416 | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ZNF507 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF573 | c.1549C>G p.Q517E (on ENST00000536220 / NM_001172692.1; = p.Q459E on NM_152360.3) | Missense Mutation (SNP) | VAF 20/445 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- ZP1 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- A1CF | c.1784G>A p.*595= (on ENST00000373993 / NM_138932.2; = p.*587= on NM_014576.4) | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV50965175; called by muse, varscan2
- ABCB5 | c.1800G>A p.L600= (on ENST00000404938 / NM_001163941.2; = p.L155= on NM_178559.6) | Silent (SNP) | VAF 23/191 reads (12%) | catalogued as COSV51722236; called by muse, mutect2, varscan2
- ACKR1 | c.738G>T p.L246= | Silent (SNP) | VAF 70/247 reads (28%) | catalogued as COSV63673481; called by muse, mutect2, varscan2
- AHR | c.2421A>G p.L807= | Silent (SNP) | VAF 93/243 reads (38%) | called by muse, mutect2, varscan2
- ASRGL1 | c.156C>A p.V52= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2
- ATP11B | c.3234C>A p.L1078= | Silent (SNP) | VAF 20/472 reads (4%) | called by muse, mutect2
- ATP13A4 | c.309C>A p.L103= | Silent (SNP) | VAF 29/496 reads (6%) | catalogued as COSV55066717; called by muse, mutect2
- BOD1L1 | c.4005A>T p.S1335= | Silent (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- BRD8 | c.3372C>T p.F1124= | Silent (SNP) | VAF 32/244 reads (13%) | called by muse, mutect2, varscan2
- C18orf21 | c.405C>G p.L135= | Silent (SNP) | VAF 26/238 reads (11%) | called by muse, mutect2
- CACNA1E | c.2550C>T p.I850= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1174745771; called by muse, varscan2
- CALCB | c.123C>A p.L41= | Silent (SNP) | VAF 84/216 reads (39%) | called by muse, mutect2, varscan2
- CAPN5 | c.504C>T p.F168= (on ENST00000456580; = p.F128= on NM_004055.5) | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV53692204; called by muse, mutect2, varscan2
- CCSER1 | c.1137A>G p.L379= | Silent (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- CDH19 | c.1389C>T p.I463= | Silent (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- CENPE | c.5955G>C p.V1985= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV54379212; called by muse, mutect2, varscan2
- CFAP65 | c.3237C>A p.T1079= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- CNR1 | c.951C>A p.I317= | Silent (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- DAB2 | c.609T>A p.T203= | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- DDIT3 | c.477G>C p.L159= | Silent (SNP) | VAF 46/299 reads (15%) | called by muse, mutect2, varscan2
- DDX18 | c.54C>G p.L18= | Silent (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- DLC1 | c.2466C>A p.L822= (on ENST00000276297 / NM_001348081.2; = p.L385= on NM_006094.5) | Silent (SNP) | VAF 7/185 reads (4%) | called by muse, mutect2
- DNAAF6 | c.222C>G p.L74= | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- DPM2 | c.57C>T p.I19= | Silent (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- DRD5 | c.282C>G p.V94= | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- EPHA3 | c.1542C>A p.A514= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- FAM117B | c.1662C>T p.S554= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as rs1202336882; called by muse, mutect2, varscan2
- FAM120B | c.2043A>G p.L681= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as rs1170529942; called by muse, mutect2
- FAT4 | c.11427G>T p.V3809= | Silent (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- FCER2 | c.612G>A p.P204= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as rs375077946, COSV100689683; called by muse, mutect2, varscan2
- FCGBP | c.6891C>T p.C2297= | Silent (SNP) | VAF 41/329 reads (12%) | called by muse, mutect2, varscan2
- FCGBP | c.4839G>T p.A1613= | Silent (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- FNBP4 | c.1155G>A p.E385= | Silent (SNP) | VAF 65/532 reads (12%) | catalogued as rs976575276; called by muse, mutect2, varscan2
- FSHR | c.1215C>T p.A405= | Silent (SNP) | VAF 55/245 reads (22%) | catalogued as rs1258874323; called by muse, mutect2, varscan2
- GFRA2 | c.1344G>A p.P448= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1343248044, COSV100152233; called by muse, mutect2
- GPR139 | c.897G>T p.T299= | Silent (SNP) | VAF 45/244 reads (18%) | catalogued as COSV100429827, COSV58503668; called by muse, mutect2, varscan2
- GPR68 | c.456C>A p.T152= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- GRID1 | c.1905C>T p.G635= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs1330722577, COSV100025233; called by muse, mutect2, varscan2
- GSS | c.156C>G p.L52= | Silent (SNP) | VAF 41/389 reads (11%) | catalogued as COSV53812252; called by muse, mutect2, varscan2
- HERC2 | c.12753C>T p.V4251= | Silent (SNP) | VAF 43/279 reads (15%) | called by muse, mutect2, varscan2
- HOXC6 | c.606C>T p.L202= | Silent (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- HS3ST5 | c.483C>T p.I161= | Silent (SNP) | VAF 87/547 reads (16%) | catalogued as COSV57140647; called by muse, mutect2, varscan2
- HTR3E | c.1344C>A p.I448= (on ENST00000415389 / NM_001256613.1; = p.I463= on NM_182589.2) | Silent (SNP) | VAF 63/657 reads (10%) | called by muse, mutect2
- HUWE1 | c.8953C>T p.L2985= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1170610397; called by muse, mutect2, varscan2
- IGHV1-18 | c.117C>A p.V39= | Silent (SNP) | VAF 28/267 reads (10%) | catalogued as rs782732886; called by muse, mutect2, varscan2
- IGSF9B | c.1977G>A p.L659= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- INPP4A | c.762C>G p.L254= | Silent (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- KCNAB1 | c.222C>A p.L74= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- KCNRG | c.214T>C p.L72= | Silent (SNP) | VAF 43/243 reads (18%) | called by muse, mutect2, varscan2
- KIF2B | c.1185T>C p.C395= | Silent (SNP) | VAF 46/139 reads (33%) | called by muse, mutect2, varscan2
- KMT5B | c.612A>T p.S204= | Silent (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- LAMC1 | c.627C>T p.F209= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- LRRC52 | c.681G>A p.R227= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as rs374391913; called by muse, mutect2, varscan2
- MACROD1 | c.669C>A p.V223= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.1788C>T p.F596= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs900300698; called by muse, mutect2, varscan2
- MCCC1 | c.126A>T p.T42= | Silent (SNP) | VAF 36/305 reads (12%) | called by muse, mutect2, varscan2
- MET | c.495G>A p.Q165= | Silent (SNP) | VAF 88/374 reads (24%) | catalogued as COSV100577745; called by muse, mutect2, varscan2
- MINDY2 | c.744C>T p.I248= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- MYH4 | c.1515G>A p.K505= | Silent (SNP) | VAF 149/322 reads (46%) | catalogued as rs755203880; called by muse, mutect2, varscan2
- MYO5A | c.4938G>A p.L1646= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as COSV62563550; called by muse, mutect2, varscan2
- NR5A2 | c.1156T>C p.L386= (on ENST00000367362 / NM_205860.3; = p.L340= on NM_003822.5) | Silent (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- NTM | c.621G>T p.V207= | Silent (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- NUP85 | c.1563C>T p.L521= | Silent (SNP) | VAF 42/448 reads (9%) | catalogued as COSV55457442; called by muse, mutect2
- OPRK1 | c.534C>T p.I178= | Silent (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- OR14C36 | c.891G>T p.V297= | Silent (SNP) | VAF 57/208 reads (27%) | catalogued as COSV100507400; called by muse, mutect2, varscan2
- OR2T3 | c.918G>A p.L306= | Silent (SNP) | VAF 62/860 reads (7%) | catalogued as rs764496272, COSV100612980, COSV100613467; called by muse, mutect2
- OR6T1 | c.99G>T p.V33= | Silent (SNP) | VAF 44/174 reads (25%) | catalogued as COSV100190278; called by muse, mutect2, varscan2
- P4HB | c.1002G>A p.L334= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV58943134; called by muse, mutect2, varscan2
- PCDHA9 | c.2235G>T p.V745= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV100969274; called by muse, mutect2, varscan2
- PCDHGA8 | c.1620G>A p.P540= | Silent (SNP) | VAF 52/85 reads (61%) | catalogued as rs1180818373, COSV53893877; called by muse, mutect2, varscan2
- PCGF2 | c.60C>G p.L20= | Silent (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- PGAP4 | c.459T>C p.F153= | Silent (SNP) | VAF 85/192 reads (44%) | catalogued as rs1211795328; called by muse, mutect2, varscan2
- PLXNC1 | c.1929A>T p.G643= | Silent (SNP) | VAF 40/157 reads (25%) | called by muse, varscan2
- PREX2 | c.1827C>T p.D609= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as COSV55805538; called by muse, mutect2, varscan2
- PRTG | c.1287C>A p.T429= | Silent (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- RPSA | c.111C>T p.Y37= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs760283784; called by muse, mutect2
- RSL1D1 | c.1317G>T p.V439= | Silent (SNP) | VAF 249/659 reads (38%) | called by muse, mutect2, varscan2
- SGCG | c.237C>T p.R79= | Silent (SNP) | VAF 46/268 reads (17%) | catalogued as rs201144588; called by muse, mutect2, varscan2
- SIGLEC5 | c.603C>T p.T201= | Silent (SNP) | VAF 23/203 reads (11%) | catalogued as rs1236888668, COSV99707788; called by muse, mutect2, varscan2
- SLC12A5 | c.411C>T p.V137= (on ENST00000454036 / NM_001134771.2; = p.V114= on NM_020708.5) | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- SLC28A3 | c.1791G>C p.A597= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs757375728; called by muse, mutect2, varscan2
- SLC46A2 | c.939C>T p.L313= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs139403102, COSV65290556; called by muse, mutect2, varscan2
- SLC7A8 | c.1206G>T p.T402= | Silent (SNP) | VAF 131/780 reads (17%) | called by muse, mutect2, varscan2
- SNTG2 | c.567T>C p.H189= | Silent (SNP) | VAF 90/817 reads (11%) | called by muse, mutect2, varscan2
- TAOK1 | c.231C>A p.V77= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- THAP9 | c.2499C>G p.V833= | Silent (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- TLN2 | c.5013C>T p.N1671= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as rs896247023; called by muse, mutect2, varscan2
- TM9SF3 | c.975C>T p.L325= | Silent (SNP) | VAF 33/212 reads (16%) | catalogued as rs562637602; called by muse, mutect2, varscan2
- TMEM98 | c.540G>T p.T180= | Silent (SNP) | VAF 76/339 reads (22%) | catalogued as rs759666021, COSV55583084; called by muse, mutect2, varscan2
- TNXB | c.9939G>A p.L3313= (on ENST00000647633; = p.L3066= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- TRHR | c.312C>A p.L104= | Silent (SNP) | VAF 109/394 reads (28%) | called by muse, mutect2, varscan2
- TTC5 | c.483C>T p.V161= | Silent (SNP) | VAF 38/234 reads (16%) | catalogued as rs758003522; called by muse, mutect2, varscan2
- UBR1 | c.2886C>G p.L962= | Silent (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2, varscan2
- UNC80 | c.606T>A p.S202= | Silent (SNP) | VAF 61/215 reads (28%) | called by muse, mutect2, varscan2
- WDR62 | c.1149C>T p.I383= | Silent (SNP) | VAF 30/434 reads (7%) | called by muse, mutect2
- ZAN | c.7404C>T p.C2468= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs552182725, COSV61806951; called by muse, mutect2, varscan2
- ZBTB16 | c.1863G>T p.L621= | Silent (SNP) | VAF 51/441 reads (12%) | called by muse, mutect2, varscan2
- ENPP2 | c.973-2047G>A | Intron (SNP) | VAF 42/158 reads (27%) | catalogued as COSV50010371; called by muse, mutect2, varscan2
- LAMA4 | c.297+2382C>A | Intron (SNP) | VAF 36/244 reads (15%) | called by muse, varscan2
- LARS2 | c.*700C>T | 3'UTR (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- SNORD115-41 | n.24T>A | RNA (SNP) | VAF 39/265 reads (15%) | called by muse, mutect2, varscan2
